Somatic mutation profile of tumor specimen HCM-BROD-0415-C71-02B (aliquot HCM-BROD-0415-C71-02B-11D-A80U-36) from HCMI case HCM-BROD-0415-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.3 years (19,455 days).
Specimen HCM-BROD-0415-C71-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca6a1a09-d7ce-442c-a232-aa930e8e2e77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0415-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0415-C71-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71e85213-e97f-494a-9cf3-1d6516f15e42

The open-access MAF lists 93 somatic variants for this specimen: 68 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 24, Frame Shift Del 7, Nonsense Mutation 3, In Frame Del 2, Intron 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 140/190 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs587782350, CM991083, COSV64291511, COSV64305247; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 134/446 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AKAP9 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 42/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs896283872, COSV100662530; called by muse, mutect2
- AMIGO2 | c.454C>A p.H152N | Missense Mutation (SNP) | VAF 122/330 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs1001005665, COSV99873506; called by muse, varscan2
- AMIGO2 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 110/314 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs774713889, COSV56974414; called by muse, varscan2
- ARHGAP21 | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 87/139 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57605752; called by muse, mutect2, varscan2
- C7 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 83/201 reads (41%) | catalogued as rs1393459238, COSV57476232; called by muse, mutect2, varscan2
- C8orf34 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 91/236 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs750592151; called by muse, mutect2, varscan2
- CACNA1A | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 172/670 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs778912392; called by muse, mutect2, varscan2
- CD209 | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 209/721 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.31); catalogued as COSV52659254; called by muse, mutect2, varscan2
- CHL1 | c.1363G>A p.V455M (on ENST00000397491 / NM_001253387.1; = p.V471M on NM_006614.4) | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775477764, COSV56596958, COSV56598034; called by muse, mutect2, varscan2
- DLEU7 | c.496G>C p.A166P | Missense Mutation (SNP) | VAF 124/322 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1339525667; called by muse, mutect2, varscan2
- DLGAP2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 242/676 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.192); catalogued as rs1291546030, COSV70094169; called by muse, mutect2
- DSCAM | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 95/206 reads (46%) | catalogued as rs1461810166, COSV68027236; called by muse, mutect2, varscan2
- FCRL1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 112/228 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs551893022, COSV63824514; called by muse, mutect2, varscan2
- GABRA6 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 99/275 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754862222, COSV50877427; called by muse, mutect2, varscan2
- HELZ2 | c.5314C>T p.P1772S (on ENST00000467148 / NM_001037335.2; = p.P1203S on NM_033405.3) | Missense Mutation (SNP) | VAF 223/478 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.059); catalogued as rs1232421413, COSV71296140; called by muse, varscan2
- KIF2B | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 184/463 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs369005833, COSV52129723; called by muse, mutect2
- LCE2A | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 209/541 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.059); catalogued as rs371432619; called by muse, mutect2, varscan2
- LRRC18 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 188/237 reads (79%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.939); catalogued as rs536518606, COSV53283082, COSV99629362; called by muse, mutect2, varscan2
- LTB4R | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 210/523 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs555617343; called by muse, mutect2, varscan2
- MBD3L2 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 175/594 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs772576142; called by muse, mutect2, varscan2
- MECOM | c.187G>A p.E63K (on ENST00000468789 / NM_001105078.4; = p.E251K on NM_004991.4) | Missense Mutation (SNP) | VAF 205/447 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as rs760397699, COSV52961960; called by muse, mutect2, varscan2
- NMBR | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766550244, COSV57802194; called by muse, varscan2
- NOBOX | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 187/639 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs750862438, COSV56194106; called by muse, mutect2, varscan2
- NUP160 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 199/478 reads (42%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV65855775; called by muse, mutect2, varscan2
- OR4D6 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 191/418 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764578155, COSV55660383, COSV55660812; called by muse, mutect2, varscan2
- PGR | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 141/356 reads (40%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs150584881; called by muse, mutect2, varscan2
- PTPRN2 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 308/1054 reads (29%) | catalogued as rs532802114, COSV67026733; called by muse, mutect2, varscan2
- PXDNL | c.3319G>A p.V1107M | Missense Mutation (SNP) | VAF 165/403 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs770252979, COSV100683091; called by muse, mutect2, varscan2
- RFPL3 | c.197C>T p.S66L (on ENST00000249007 / NM_001098535.1; = p.S37L on NM_006604.2) | Missense Mutation (SNP) | VAF 178/604 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as rs370716010, COSV50748125; called by muse, mutect2
- RIMS2 | c.1411C>T p.R471W (on ENST00000666250 / NM_001348490.2; = p.R279W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 147/374 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566248680, COSV51698013; called by muse, mutect2, varscan2
- STOX2 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 237/321 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1321820332; called by muse, mutect2, varscan2
- TBK1 | c.100T>G p.L34V | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs1298720550; called by muse, mutect2, varscan2
- VSIR | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 216/264 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312702295; called by muse, mutect2, varscan2
- ZNF717 | c.1698T>A p.N566K | Missense Mutation (SNP) | VAF 108/485 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as rs1308578701; called by muse, mutect2, varscan2
- ZNFX1 | c.5179_5183del p.E1727Kfs*11 | Frame Shift Del (DEL) | VAF 186/433 reads (43%) | catalogued as rs776308098; called by mutect2, pindel, varscan2
- AC099489.1 | c.3017C>T p.T1006I | Missense Mutation (SNP) | VAF 129/309 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- AKAP9 | c.4504A>G p.T1502A | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BCO2 | c.1136G>T p.R379I | Missense Mutation (SNP) | VAF 114/366 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- CARS2 | c.811_812del p.I271Pfs*13 | Frame Shift Del (DEL) | VAF 59/220 reads (27%) | called by pindel, varscan2
- CSMD3 | c.10705A>C p.K3569Q (on ENST00000297405 / NM_001363185.1; = p.K3400Q on NM_052900.3) | Missense Mutation (SNP) | VAF 140/370 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DLGAP4 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 217/499 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DNAH3 | c.2660T>A p.M887K | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- EXTL3 | c.806del p.D269Vfs*69 | Frame Shift Del (DEL) | VAF 138/465 reads (30%) | called by mutect2, pindel, varscan2
- FER1L6 | c.3774A>T p.K1258N | Missense Mutation (SNP) | VAF 144/299 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- FYTTD1 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 143/317 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDF9 | c.146_149del p.L49Cfs*4 | Frame Shift Del (DEL) | VAF 159/496 reads (32%) | called by mutect2, pindel, varscan2
- GGT6 | c.545C>T p.A182V (on ENST00000574154 / NM_001122890.3; = p.A150V on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 231/558 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- GRIN2D | c.1976T>C p.V659A | Missense Mutation (SNP) | VAF 61/550 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIAA0408 | c.828_834del p.N276Kfs*16 | Frame Shift Del (DEL) | VAF 80/296 reads (27%) | called by mutect2, pindel, varscan2
- KIAA1328 | c.1734A>G p.*578Wext*7 | Nonstop Mutation (SNP) | VAF 69/151 reads (46%) | called by muse, mutect2, varscan2
- LDHD | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 221/547 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LINGO3 | c.1086_1094delinsTGT p.W362_Q365delinsCV | In Frame Del (DEL) | VAF 158/876 reads (18%) | called by pindel, varscan2*
- MACF1 | c.7889G>A p.R2630K | Missense Mutation (SNP) | VAF 138/340 reads (41%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 284/680 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MOB3B | c.212T>C p.I71T | Missense Mutation (SNP) | VAF 10/287 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- PHLDA2 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 228/754 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- POU2F2 | c.213T>A p.D71E | Missense Mutation (SNP) | VAF 189/648 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PPM1A | c.1070T>C p.V357A | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.247); called by muse, mutect2
- PRKACA | c.297_315del p.F101Sfs*47 | Frame Shift Del (DEL) | VAF 85/438 reads (19%) | called by mutect2, pindel, varscan2
- ROPN1B | c.284_301del p.K95_P100del | In Frame Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- TBRG4 | c.1070T>G p.V357G | Missense Mutation (SNP) | VAF 120/405 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TOGARAM1 | c.4898-1G>A p.X1633_splice | Splice Site (SNP) | VAF 97/218 reads (44%) | called by muse, mutect2, varscan2
- TRIM24 | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 210/700 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC27 | c.306del p.Q102Hfs*40 | Frame Shift Del (DEL) | VAF 92/325 reads (28%) | called by mutect2, pindel, varscan2
- ZNF208 | c.2221G>T p.V741L | Missense Mutation (SNP) | VAF 96/348 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.083); called by mutect2, varscan2
- ZNF717 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 109/488 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- ARHGEF4 | c.711C>T p.A237= | Silent (SNP) | VAF 43/462 reads (9%) | catalogued as rs774224543; called by muse, mutect2
- CCDC160 | c.912A>G p.K304= | Silent (SNP) | VAF 14/446 reads (3%) | called by muse, mutect2
- CD300C | c.90C>T p.T30= | Silent (SNP) | VAF 105/292 reads (36%) | catalogued as rs777405831, COSV58169934, COSV58170907; called by muse, mutect2, varscan2
- CHAF1A | c.729G>A p.Q243= | Silent (SNP) | VAF 171/634 reads (27%) | called by muse, mutect2, varscan2
- CHIC1 | c.108G>A p.S36= | Silent (SNP) | VAF 322/783 reads (41%) | called by muse, varscan2
- CNTNAP2 | c.1293G>A p.V431= | Silent (SNP) | VAF 146/478 reads (31%) | called by muse, mutect2, varscan2
- DAB2IP | c.1212C>T p.C404= (on ENST00000408936; = p.C376= on NM_032552.3) | Silent (SNP) | VAF 145/348 reads (42%) | catalogued as rs896396352, COSV99406407; called by muse, mutect2, varscan2
- DMBT1 | c.720C>T p.G240= | Silent (SNP) | VAF 216/260 reads (83%) | catalogued as rs199795989, COSV57561961; called by muse, varscan2
- GATA6 | c.126G>A p.S42= | Silent (SNP) | VAF 261/629 reads (41%) | called by muse, mutect2, varscan2
- JMJD1C | c.6781T>C p.L2261= | Silent (SNP) | VAF 101/183 reads (55%) | called by muse, mutect2, varscan2
- KIAA1109 | c.10041A>G p.T3347= | Silent (SNP) | VAF 81/248 reads (33%) | called by muse, mutect2, varscan2
- LPA | c.2736G>A p.A912= | Silent (SNP) | VAF 103/261 reads (39%) | catalogued as rs1344439639; called by muse, mutect2, varscan2
- NDUFA13 | c.414C>T p.H138= | Silent (SNP) | VAF 135/435 reads (31%) | catalogued as rs755798891; called by muse, mutect2, varscan2
- NOD2 | c.321C>T p.A107= | Silent (SNP) | VAF 95/513 reads (19%) | catalogued as rs1241091187; called by muse, mutect2, varscan2
- OR4K5 | c.351G>A p.S117= | Silent (SNP) | VAF 113/465 reads (24%) | catalogued as rs765795652, COSV60002373, COSV60003499; called by muse, mutect2, varscan2
- RBMXL3 | c.987C>T p.Y329= | Silent (SNP) | VAF 303/710 reads (43%) | catalogued as rs1207892597, COSV100407257; called by muse, mutect2
- RMDN3 | c.537C>G p.A179= | Silent (SNP) | VAF 110/260 reads (42%) | called by muse, mutect2, varscan2
- RNF128 | c.366C>T p.R122= | Silent (SNP) | VAF 183/411 reads (45%) | catalogued as COSV55249509; called by muse, mutect2, varscan2
- RYR2 | c.8742G>A p.T2914= | Silent (SNP) | VAF 84/219 reads (38%) | catalogued as rs751520306, COSV63670560; called by muse, mutect2, varscan2
- SLC6A20 | c.615C>T p.C205= | Silent (SNP) | VAF 129/314 reads (41%) | catalogued as rs779053318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THSD7B | c.2712G>A p.K904= | Silent (SNP) | VAF 107/234 reads (46%) | catalogued as rs771913389; called by muse, mutect2, varscan2
- TPO | c.1260G>A p.A420= | Silent (SNP) | VAF 294/642 reads (46%) | catalogued as rs1358820098, COSV61094840; called by muse, varscan2
- TRIB2 | c.13A>C p.R5= | Silent (SNP) | VAF 134/307 reads (44%) | called by muse, mutect2, varscan2
- ZNF546 | c.1359A>G p.Q453= | Silent (SNP) | VAF 160/644 reads (25%) | catalogued as rs1449211629; called by muse, mutect2, varscan2
- SYNE1 | c.1351-211_1351-205del | Intron (DEL) | VAF 75/240 reads (31%) | called by mutect2, pindel, varscan2
